Somatic mutation profile of tumor specimen 0DUUQ7 from CCDI case PBCKCZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Smooth muscle tumor of uncertain malignant potential; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 15.5 years (5,675 days).
Specimen 0DUUQ7: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 572ed1b9-7554-42c0-827a-ceebe2b2ae1a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUUPJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/133537a2-d83a-4e87-a3bc-49d4916c4483

The open-access MAF lists 65 somatic variants for this specimen: 41 protein-altering or splice-affecting, 13 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 13, 3'UTR 4, Nonsense Mutation 3, Splice Site 2, Splice Region 2, RNA 2, Intron 2, 5'UTR 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC004922.1 | c.1336G>A p.G446S | Missense Mutation (SNP) | VAF 60/360 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as rs1342933026; called by muse, mutect2, varscan2
- CARD14 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 62/244 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs538572480; called by muse, varscan2
- CDKL5 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 26/368 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV66110209; called by muse, mutect2
- GABBR2 | c.2584C>T p.P862S | Missense Mutation (SNP) | VAF 90/277 reads (32%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.015); catalogued as rs891861059, COSV52299574; ClinVar: uncertain significance; called by muse, varscan2
- KCNK9 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 73/354 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57278639; called by muse, mutect2, varscan2
- MYH15 | c.2855G>T p.G952V | Missense Mutation (SNP) | VAF 16/416 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs1345340125; called by muse, mutect2
- NEUROG2 | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 46/293 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as rs751717068; called by muse, mutect2, varscan2
- PRKDC | c.3109C>T p.L1037F | Missense Mutation (SNP) | VAF 34/540 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV58050103; called by muse, mutect2
- R3HDM2 | c.2756A>G p.E919G | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV60414422; called by muse, mutect2
- SOX11 | c.87C>A p.C29* | Nonsense Mutation (SNP) | VAF 47/311 reads (15%) | catalogued as CM162582, COSV58984276; called by muse, mutect2, varscan2
- ZMYM3 | c.3385C>T p.R1129* | Nonsense Mutation (SNP) | VAF 77/767 reads (10%) | catalogued as COSV58738062; called by muse, mutect2
- ZNF805 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 59/413 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.328); catalogued as rs777403501; called by muse, mutect2, varscan2
- AKR1C4 | c.226A>G p.R76G | Missense Mutation (SNP) | VAF 14/502 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- ALDOB | c.890A>T p.K297I | Missense Mutation (SNP) | VAF 118/318 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ALPP | c.999G>C p.E333D | Missense Mutation (SNP) | VAF 71/796 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AMTN | c.361C>A p.Q121K | Missense Mutation (SNP) | VAF 43/406 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- AQP10 | c.105+2T>C p.X35_splice | Splice Site (SNP) | VAF 71/189 reads (38%) | called by muse, mutect2, varscan2
- BCOR | c.521A>C p.D174A | Missense Mutation (SNP) | VAF 122/482 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CBARP | c.872C>G p.A291G (on ENST00000382477; = p.A271G on NM_152769.3) | Missense Mutation (SNP) | VAF 26/234 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- CRACD | c.169A>G p.I57V | Missense Mutation (SNP) | VAF 55/355 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GLRA2 | c.1160C>A p.T387K | Missense Mutation (SNP) | VAF 246/541 reads (45%) | SIFT tolerated (0.79); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- HR | c.1406-1G>A p.X469_splice | Splice Site (SNP) | VAF 32/352 reads (9%) | called by muse, mutect2
- MAGEB18 | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 68/690 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MUC19 | n.19372C>A | Splice Region (SNP) | VAF 36/246 reads (15%) | called by muse, mutect2, varscan2
- MYH1 | c.2639A>T p.K880I | Missense Mutation (SNP) | VAF 120/620 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, varscan2
- MYO1F | c.2444A>G p.D815G | Missense Mutation (SNP) | VAF 51/499 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NAT8 | c.382G>C p.D128H | Missense Mutation (SNP) | VAF 49/339 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- NFYA | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 115/380 reads (30%) | called by muse, mutect2, varscan2
- OCRL | c.2099C>A p.T700N | Missense Mutation (SNP) | VAF 15/405 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.017); called by muse, mutect2
- PCLO | c.15006A>G p.E5002= | Splice Region (SNP) | VAF 25/261 reads (10%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.845A>T p.Q282L | Missense Mutation (SNP) | VAF 134/505 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SDK1 | c.5500G>A p.G1834S | Missense Mutation (SNP) | VAF 164/480 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNX30 | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 30/219 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- SPATA31E1 | c.50A>T p.E17V | Missense Mutation (SNP) | VAF 136/402 reads (34%) | PolyPhen benign (0.104); called by muse, mutect2, varscan2
- TBX2 | c.1630G>C p.A544P | Missense Mutation (SNP) | VAF 136/477 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- TOR1B | c.529G>C p.D177H | Missense Mutation (SNP) | VAF 44/333 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- VRK1 | c.1167A>T p.R389S | Missense Mutation (SNP) | VAF 51/369 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- WDFY1 | c.115G>C p.V39L | Missense Mutation (SNP) | VAF 36/260 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, varscan2
- XRRA1 | c.2284C>G p.P762A | Missense Mutation (SNP) | VAF 41/375 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZIK1 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 27/310 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZMYM3 | c.2364G>T p.E788D | Missense Mutation (SNP) | VAF 59/800 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.023); called by muse, mutect2
- ABCA7 | c.1164C>T p.D388= | Silent (SNP) | VAF 93/261 reads (36%) | catalogued as rs754600576, COSV54027468; called by muse, mutect2, varscan2
- CFAP47 | c.5013G>A p.T1671= | Silent (SNP) | VAF 35/436 reads (8%) | catalogued as rs765599254, COSV57975553; called by muse, mutect2
- DENND1C | c.1839G>A p.P613= | Silent (SNP) | VAF 74/605 reads (12%) | catalogued as rs770244356; called by muse, mutect2, varscan2
- DNAH2 | c.4506C>G p.L1502= | Silent (SNP) | VAF 206/380 reads (54%) | called by muse, mutect2, varscan2
- HERC1 | c.5313T>C p.S1771= | Silent (SNP) | VAF 53/409 reads (13%) | called by muse, mutect2, varscan2
- KRT3 | c.1719C>G p.G573= | Silent (SNP) | VAF 34/213 reads (16%) | called by muse, mutect2, varscan2
- KRT76 | c.1095C>T p.A365= | Silent (SNP) | VAF 44/424 reads (10%) | catalogued as rs1462445524; called by muse, mutect2
- MXD4 | c.240G>A p.V80= | Silent (SNP) | VAF 26/236 reads (11%) | called by muse, mutect2, varscan2
- NDUFAF1 | c.609C>G p.S203= | Silent (SNP) | VAF 18/353 reads (5%) | called by muse, mutect2
- OR51E1 | c.420G>A p.T140= | Silent (SNP) | VAF 48/296 reads (16%) | catalogued as rs547567048, COSV67810477; called by muse, varscan2
- RYR2 | c.9715C>T p.L3239= | Silent (SNP) | VAF 31/295 reads (11%) | catalogued as rs1351601477; called by muse, mutect2, varscan2
- SV2B | c.114C>A p.G38= | Silent (SNP) | VAF 48/360 reads (13%) | called by muse, mutect2, varscan2
- TRMT5 | c.285C>T p.N95= | Silent (SNP) | VAF 53/562 reads (9%) | called by muse, mutect2
- AIP | c.-38G>C | 5'UTR (SNP) | VAF 49/371 reads (13%) | catalogued as COSV99653907; called by muse, mutect2
- BEX1 | c.*7A>T | 3'UTR (SNP) | VAF 44/270 reads (16%) | called by muse, mutect2, varscan2
- MS4A4A | c.547-18T>C | Intron (SNP) | VAF 31/118 reads (26%) | called by muse, mutect2, varscan2
- PATL2 | c.-31G>A | 5'UTR (SNP) | VAF 34/212 reads (16%) | catalogued as rs1294972032; called by muse, mutect2, varscan2
- RIMBP3C | c.*49A>G | 3'UTR (SNP) | VAF 4/19 reads (21%) | called by mutect2, varscan2
- RTBDN | chr19:12834884 G>A | 5'Flank (SNP) | VAF 19/166 reads (11%) | called by muse, mutect2, varscan2
- SCML1 | c.*87C>T | 3'UTR (SNP) | VAF 25/206 reads (12%) | catalogued as rs1316488343; called by muse, mutect2, varscan2
- SLC6A7 | c.*12G>C | 3'UTR (SNP) | VAF 33/283 reads (12%) | called by muse, mutect2, varscan2
- SPATA31C1 | n.3494G>A | RNA (SNP) | VAF 23/134 reads (17%) | called by muse, mutect2, varscan2
- SSPOP | n.13556G>A | RNA (SNP) | VAF 44/174 reads (25%) | catalogued as rs376465293; called by muse, mutect2, varscan2
- TAF15 | c.7+28C>A | Intron (SNP) | VAF 20/196 reads (10%) | called by mutect2, varscan2
